Somatic mutation profile of tumor specimen TCGA-DM-A28E-01A (aliquot TCGA-DM-A28E-01A-11D-A16V-10) from TCGA case TCGA-DM-A28E, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.8 years (26,602 days).
Specimen TCGA-DM-A28E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0d8e2c9-969d-4555-b0dc-967fed945900.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A28E-10A (Blood Derived Normal), aliquot TCGA-DM-A28E-10A-01D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cf77321-1c66-44a7-b182-78ac52289eb1

The open-access MAF lists 90 somatic variants for this specimen: 70 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 19, Frame Shift Del 7, Nonsense Mutation 6, Intron 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as rs587779783, CM960067, COSV57322578; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 51/134 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 21/26 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 7/14 reads (50%) | catalogued as COSV99546265; called by muse, mutect2, varscan2
- ANKRD30A | c.1190G>C p.S397T (on ENST00000611781; = p.S341T on NM_052997.2) | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.153); catalogued as COSV100652518; called by muse, mutect2, varscan2
- ANO2 | c.2266G>A p.V756M (on ENST00000356134 / NM_001278597.3; = p.V760M on NM_001278596.3) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs199625786, COSV59036482; called by muse, mutect2, varscan2
- APC | c.4356del p.P1453Lfs*20 | Frame Shift Del (DEL) | VAF 31/90 reads (34%) | catalogued as COSV57374219; called by mutect2, pindel, varscan2
- ARR3 | c.323A>G p.N108S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.416); catalogued as rs1484196601, COSV57205868; called by muse, mutect2, varscan2
- ATP5F1B | c.992A>G p.Y331C | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56261540; called by muse, mutect2, varscan2
- CACNA2D3 | c.1708G>A p.V570M | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs764866239, COSV99867873; called by muse, mutect2, varscan2
- CHD6 | c.7987del p.D2663Tfs*59 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as COSV64690019; called by mutect2, pindel, varscan2
- CLDN10 | c.220+2T>C p.X74_splice | Splice Site (SNP) | VAF 25/39 reads (64%) | catalogued as COSV100176015; called by muse, mutect2, varscan2
- COL1A2 | c.2776C>T p.R926C | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745363291, COSV51967649, COSV99798007; called by muse, mutect2, varscan2
- COL6A3 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as rs753651742, COSV55082456; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUL4B | c.2265G>T p.M755I | Missense Mutation (SNP) | VAF 101/155 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV100340006; called by muse, mutect2, varscan2
- CYBC1 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs768374410, COSV60065799; called by muse, mutect2, varscan2
- DIXDC1 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782795876, COSV101098127; called by muse, mutect2, varscan2
- DNAH11 | c.3010G>T p.D1004Y | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100175983, COSV60947459, COSV60981523; called by muse, mutect2, varscan2
- DNAH11 | c.10637C>T p.T3546M | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs374549012; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.2821G>T p.V941F | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99442779; called by muse, mutect2, varscan2
- ERMARD | c.2023A>T p.K675* | Nonsense Mutation (SNP) | VAF 22/75 reads (29%) | catalogued as rs1041899050, COSV100824500; called by muse, mutect2, varscan2
- ERRFI1 | c.166C>A p.L56M | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV101087875; called by muse, mutect2, varscan2
- FOXD4L5 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1221899275, COSV101072967; called by muse, mutect2, varscan2
- GIMAP8 | c.302T>G p.I101S | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV100217233; called by muse, mutect2, varscan2
- GTPBP8 | c.391_394del p.F131Hfs*20 | Frame Shift Del (DEL) | VAF 68/154 reads (44%) | catalogued as COSV55607312; called by mutect2, pindel, varscan2
- GYS1 | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs994882983, COSV99620224; called by muse, mutect2, varscan2
- HAVCR2 | c.276del p.D92Efs*4 | Frame Shift Del (DEL) | VAF 41/114 reads (36%) | catalogued as COSV57154518; called by mutect2, pindel, varscan2
- HEXD | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs770075737, COSV60065794; called by muse, mutect2, varscan2
- HYDIN | c.1147C>T p.R383* | Nonsense Mutation (SNP) | VAF 27/88 reads (31%) | catalogued as rs543553606, COSV55496566, COSV99863380; called by muse, varscan2
- IL18RAP | c.881C>G p.S294C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV51824485, COSV99961656; called by muse, mutect2, varscan2
- INTS4 | c.948C>A p.F316L | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV101417097; called by muse, mutect2, varscan2
- IVL | c.815A>G p.Q272R | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV100908059; called by muse, mutect2, varscan2
- KIF2B | c.910C>A p.Q304K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV52131002, COSV52131508; called by muse, mutect2, varscan2
- LARP4 | c.1843C>T p.R615* | Nonsense Mutation (SNP) | VAF 24/49 reads (49%) | catalogued as COSV53324578; called by muse, mutect2, varscan2
- MCOLN3 | c.1460G>C p.S487T | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100352499, COSV62015339; called by muse, mutect2, varscan2
- NLGN4X | c.2294G>A p.R765H | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1323836608, COSV52027286; called by muse, mutect2, varscan2
- NOS1 | c.2923C>T p.R975C | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771520384, COSV100499775; called by muse, mutect2, varscan2
- P2RY6 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs773575254, COSV62937196; called by muse, mutect2, varscan2
- PCDHA11 | c.2228C>T p.A743V | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.356); catalogued as COSV56551689; called by muse, mutect2, varscan2
- PCDHA12 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV56484482; called by muse, mutect2, varscan2
- PCDHB13 | c.2062G>A p.V688I | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as COSV53392998; called by muse, mutect2, varscan2
- PLEC | c.8051G>A p.R2684Q (on ENST00000322810 / NM_201380.4; = p.R2574Q on NM_000445.5) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1554688726, COSV100508881; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRZ1 | c.3179A>G p.N1060S | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs529791225, COSV66444141; called by muse, mutect2, varscan2
- RARS1 | c.422_425del p.I141Tfs*25 | Frame Shift Del (DEL) | VAF 41/95 reads (43%) | catalogued as COSV51565689; called by mutect2, pindel, varscan2
- RASGRF2 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99428167; called by muse, mutect2, varscan2
- SATB2 | c.1541A>G p.Q514R | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53484296; called by muse, mutect2, varscan2
- SHROOM4 | c.3293C>T p.A1098V | Missense Mutation (SNP) | VAF 76/131 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99172940; called by muse, mutect2, varscan2
- SLC25A14 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 96/316 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs768683792, COSV54417208; called by muse, mutect2, varscan2
- SLC7A3 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV53228370; called by muse, mutect2, varscan2
- SPOPL | c.329A>G p.K110R | Missense Mutation (SNP) | VAF 83/204 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.844); catalogued as rs1335825764, COSV54515957; called by muse, mutect2, varscan2
- SPTBN2 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV100017837; called by muse, mutect2, varscan2
- SSR4 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 135/212 reads (64%) | SIFT tolerated (0.94); PolyPhen benign (0.038); catalogued as COSV99472840; called by muse, mutect2, varscan2
- SV2A | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs782157459, COSV64965762; called by muse, mutect2, varscan2
- TENT5C | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs764287568, COSV101032650; called by muse, mutect2, varscan2
- TMEM131 | c.2800G>A p.E934K | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1305587044, COSV51784370; called by muse, mutect2
- TMEM74B | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.025); catalogued as COSV67892216; called by muse, varscan2
- TMUB2 | c.716del p.H239Pfs*76 (on ENST00000538716 / NM_001353177.2; = p.H219Pfs*76 on NM_024107.3 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | catalogued as COSV60229729; called by mutect2, pindel, varscan2
- TNN | c.1589A>G p.E530G | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV99510653; called by muse, mutect2, varscan2
- USP17L2 | c.1096C>A p.Q366K | Missense Mutation (SNP) | VAF 76/306 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0.055); catalogued as rs536115308, COSV100414472; called by muse, mutect2, varscan2
- USP28 | c.1933C>G p.L645V | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99134338; called by muse, mutect2, varscan2
- USP9X | c.6226A>T p.I2076F | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.045); catalogued as COSV100198237; called by muse, mutect2
- VCAN | c.7414C>T p.P2472S | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV99424126; called by muse, mutect2, varscan2
- XKR4 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 96/198 reads (48%) | catalogued as COSV100533831, COSV59299905, COSV59312309; called by muse, mutect2, varscan2
- ZMYM6 | c.3777T>A p.N1259K | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV100592943; called by muse, mutect2, varscan2
- ZNF569 | c.1911T>G p.S637R | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV100386184; called by muse, mutect2, varscan2
- ZNF700 | c.1868A>C p.K623T | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54314926; called by muse, mutect2, varscan2
- ZSWIM5 | c.1092G>A p.M364I | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs774869426, COSV100655199; called by muse, mutect2, varscan2
- CCNJL | c.1176dup p.V393Rfs*8 | Frame Shift Ins (INS) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- CCR10 | c.1039del p.S347Lfs*27 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | called by mutect2, pindel, varscan2
- SDK1 | c.6028T>G p.F2010V | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- AAK1 | c.1038G>A p.K346= | Silent (SNP) | VAF 53/144 reads (37%) | catalogued as COSV65907492; called by muse, mutect2, varscan2
- CEP250 | c.298C>T p.L100= | Silent (SNP) | VAF 96/256 reads (38%) | catalogued as COSV100698657; called by muse, mutect2, varscan2
- CSRNP3 | c.522A>G p.L174= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as rs1558971393, COSV100084821; called by muse, mutect2, varscan2
- DDX11 | c.1863T>C p.G621= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as COSV52509614, COSV52511310; called by muse, mutect2, varscan2
- EVA1A | c.117T>A p.V39= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99285194; called by mutect2, varscan2
- FNDC1 | c.1416C>T p.P472= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV99794415; called by muse, mutect2
- KCNH7 | c.198C>T p.C66= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs368853485, COSV59790126; called by muse, mutect2, varscan2
- KCNIP1 | c.78C>T p.T26= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV66181133; called by muse, mutect2, varscan2
- NCOA2 | c.810T>C p.F270= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV101475890; called by muse, mutect2, varscan2
- NCOA6 | c.1965T>A p.L655= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV100749854; called by muse, mutect2, varscan2
- PAK3 | c.534G>A p.E178= (on ENST00000262836 / NM_001324328.2; = p.E163= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 169/305 reads (55%) | catalogued as COSV99456050; called by muse, mutect2, varscan2
- PCDHB6 | c.300G>A p.P100= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs781947621, COSV99169856; called by muse, mutect2, varscan2
- PLD1 | c.382A>C p.R128= | Silent (SNP) | VAF 55/113 reads (49%) | catalogued as COSV100577431; called by muse, mutect2, varscan2
- POTEE | c.2157C>T p.A719= | Silent (SNP) | VAF 70/175 reads (40%) | catalogued as rs1047270224, COSV100386265; called by muse, mutect2, varscan2
- SLC35F4 | c.138A>G p.R46= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV100333363, COSV60267368; called by muse, mutect2
- TNPO2 | c.2556G>A p.P852= (on ENST00000425528 / NM_001382240.1; = p.P842= on NM_013433.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs752878454, COSV100790250; called by muse, mutect2, varscan2
- TNR | c.201C>T p.H67= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as rs755838255, COSV99686610; called by muse, mutect2, varscan2
- TNXB | c.5298G>A p.P1766= (on ENST00000647633; = p.P1519= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as rs747837767, COSV64472684; called by muse, mutect2, varscan2
- ZNF384 | c.633T>C p.Y211= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100158063; called by muse, mutect2, varscan2
- VGLL4 | c.255-17280A>G | Intron (SNP) | VAF 16/22 reads (73%) | catalogued as COSV56074983; called by muse, mutect2, varscan2
